Somatic mutation profile of tumor specimen MP2PRT-PATLPU-TMP1-A (aliquot MP2PRT-PATLPU-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATLPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,273 days).
Specimen MP2PRT-PATLPU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f0739e8-43b0-401b-9618-046db4eab9ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLPU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLPU-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b85dd9-58d7-46a5-8948-d3892fc9a572

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP3 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs767623836; called by muse, varscan2
- FMOD | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs374392393; called by muse, mutect2
- IKZF3 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 84/223 reads (38%) | catalogued as rs572431209, COSV53099468; called by muse, mutect2, varscan2
- LOXHD1 | c.3830G>A p.R1277H | Missense Mutation (SNP) | VAF 147/410 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs775337046, COSV56069644; called by muse, mutect2, varscan2
- PHYH | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560532343; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 98/282 reads (35%) | catalogued as rs768873484; called by mutect2, varscan2
- APOB | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 161/454 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CUL3 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IKZF1 | c.1470del p.F490Lfs*20 | Frame Shift Del (DEL) | VAF 156/413 reads (38%) | called by mutect2, pindel*, varscan2
- MRTFA | c.1694C>G p.T565R | Missense Mutation (SNP) | VAF 219/575 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUP188 | c.4407C>A p.H1469Q | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- TRGJP1 | chr7:38276316 del TATC | Missense Mutation (DEL) | VAF 33/157 reads (21%) | called by pindel*, varscan2
- WNK4 | c.1970T>C p.M657T | Missense Mutation (SNP) | VAF 19/448 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- PAK5 | c.42G>A p.P14= | Silent (SNP) | VAF 120/338 reads (36%) | catalogued as rs370805526, COSV62041063; called by muse, mutect2, varscan2
- TBC1D5 | c.505A>C p.R169= | Silent (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
